CCDI case PBCTZW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2c350970-dfb3-4fee-921d-8388ca08918a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.2 years (5,556 days).

Biospecimens (3 samples)
- Sample 0DZK4X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZK5B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DZK5H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
